Surgical pathology report (de-identified scan), TCGA case TCGA-HC-8260, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-8260-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. Soft tissue, right lateral margin of prostatectomy, biopsy:
No malignancy identified.

B. Lymph nodes, pelvic, resection; negative for malignancy, nine nodes.

C. Prostate gland, radical prostatectomy:

Tumor Characteristics:

1. Histologic type: Adenocarcinoma, conventional type.
2. Prostate size: 35.7 grams.
3. Tumor quantitation: Malignancy is present peripherally and in the apex, bilaterally, and accounts for an estimated 25% of the total prostate volume.
4. Gleason grade:
- a. Primary pattern: 3/5.
- b. Secondary pattern: 4/5.
- c. Total Gleason score: 7/10.
5. Extraprostatic extension: Not identified.
6. Seminal vesicle involvement: Not identified.
7. Lymphovascular space invasion: Not identified.
8. High grade PIN: Present focally.
9. Perineural invasion: Present, and extensive.
9. Treatment effect: Not identified.

Surgical Margin Status:

1. Malignancy extends to the inked left posterior apical margin.
2. Malignancy extends to less than 0.05 cm in multiple additional areas, bilaterally.

Lymph Node Status:

1. See part B.

Other:

1. pTNM stage: pT2c, N0.

Electronic Signature: [REDACTED]

COMMENTS:

No prior material for review and comparison is identified in our files. Correlation with previous biopsy material is suggested.

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Prostate cancer

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Right lateral margin
- B. Pelvic lymph nodes
- C. Prostate

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received in three formalin filled containers labeled with the patient's name

A. Additionally labeled right lateral margin and contains a 1.3 x 1.0 x 0.7 cm pink-tan rubbery, cauterized soft tissue. The specimen is trisected and entirely submitted in cassette A labeled

B. Additionally labeled pelvic lymph node and contains two yellow-tan fibrofatty soft tissues 2.8 x 2.0 x 1.3 cm and 3.5 x 2.5 x 1.0 cm. Designation is not

[page 2 of 2]
offered or possible. On section and palpation, multiple firm fatty possible lymph nodes are identified ranging from 0.1 up to 2.5 cm in greatest dimension. They are entirely submitted in cassettes B1-4 labeled [redacted] designated as follows: B1—five whole possible lymph nodes; B2—four whole possible lymph nodes; B3-4—one whole possible lymph node, serially sectioned.

C. Additionally labeled prostate and contains a 35.7 gram, 4.3 x 4.3 x 3.5 cm prostate received with attached bilateral adnexa which has overall dimensions of 4.8 x 2.5 x 0.7 cm. The prostatic capsule is pink-tan and shaggy. The specimen is inked as follows: right side - blue and left side - black. The base and apical margins are coned and serially sectioned. The remainder of the gland is serially sectioned from apex to base to reveal a pink-tan focally cystic cut surface with diffuse periurethral nodularity. Discrete masses are not identified. Representative sections are submitted in cassettes C1-18 labeled [redacted] designated as follows: 1—right prostate/seminal vesicle junction; 2—left prostate/seminal vesicle junction; 3 and 4—apical margin, perpendicular; 5 and 6—base margin, perpendicular; 7-9—right anterior, apex to base; 10-12—right posterior, apex to base; 13-15—left anterior, apex to base; 16-18—left posterior, apex to base. Additionally, a yellow and green cassette are submitted for [redacted] research each labeled [redacted]

Source: NCI Genomic Data Commons file 618c9766-b4d8-4611-bf62-1ae3eb981ad8 (TCGA-HC-8260.12D41624-F0A9-4BA1-AA55-18FEA0B733AF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).